Gene-level copy-number profile of tumor specimen TCGA-2A-A8VL-01A from TCGA case TCGA-2A-A8VL, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 51.1 years (18,658 days).
Specimen TCGA-2A-A8VL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.c1624780-5ee0-4c27-be4a-7367f815cc81.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2A-A8VL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6af47b74-ce0f-495d-bdeb-0d5b967a3d0f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,577; copy number 2: 55,144; copy number 3: 93; copy number 5: 3; copy number 6: 1; copy number 7: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2A-A8VL-01A-21D-A376-01): tumor purity 0.5, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:66,042,500–66,050,718, 1 gene, copy number 7: PDE4B-AS1.
- chr8:43,672,823–46,028,892, 3 genes, copy number 5: AC139365.2, AC139365.1, AC118650.1.
- chr12:91,050,491–91,058,024, 1 gene, copy number 6: KERA.

Autosomal genes at a single copy (total copy number 1): 2,196. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
